Somatic mutation profile of tumor specimen TCGA-BJ-A28T-01A (aliquot TCGA-BJ-A28T-01A-11D-A16O-08) from TCGA case TCGA-BJ-A28T, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.8 years (12,698 days).
Specimen TCGA-BJ-A28T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cecdf093-b287-43cb-a0ef-ebf69eb2be5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A28T-10A (Blood Derived Normal), aliquot TCGA-BJ-A28T-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e71f3a5a-0fd9-4160-8874-2040efed32c1

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC35D2 | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53562902; called by muse, mutect2
